Somatic mutation profile of tumor specimen TCGA-CJ-5689-01A (aliquot TCGA-CJ-5689-01A-11D-1534-10) from TCGA case TCGA-CJ-5689, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-CJ-5689-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c877c59-eb17-48d3-ae2d-6843a304cc1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-5689-11A (Solid Tissue Normal), aliquot TCGA-CJ-5689-11A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0354b1ea-ae4e-474f-a7a2-02affa1096e3

The open-access MAF lists 86 somatic variants for this specimen: 65 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 20, Nonsense Mutation 8, Frame Shift Del 5, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.10559A>G p.D3520G | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as COSV100040668; called by muse, mutect2
- ANK2 | c.4132G>T p.G1378* | Nonsense Mutation (SNP) | VAF 129/540 reads (24%) | catalogued as COSV52155458, COSV99998667; called by muse, mutect2, varscan2
- ANKRD52 | c.1595G>C p.C532S | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV57283704, COSV99920928; called by muse, mutect2, varscan2
- AP001781.2 | c.236G>C p.R79T | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.151); catalogued as COSV99499360; called by muse, mutect2, varscan2
- AP2A1 | c.2904C>G p.H968Q | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.057); catalogued as COSV100570935; called by muse, mutect2
- C20orf85 | c.47T>A p.L16H | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV100959323; called by muse, mutect2, varscan2
- CCDC191 | c.317A>T p.E106V | Missense Mutation (SNP) | VAF 59/357 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99877791; called by muse, mutect2, varscan2
- CNTNAP1 | c.3170A>G p.Y1057C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99225971; called by muse, mutect2
- CTDP1 | c.2567G>A p.S856N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs887852526, COSV99309948; called by muse, mutect2, varscan2
- CZIB | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 58/304 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as COSV99597987; called by muse, mutect2, varscan2
- DAAM2 | c.989T>C p.F330S | Missense Mutation (SNP) | VAF 16/368 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV99224129; called by muse, mutect2
- DSCAM | c.5127A>T p.Q1709H | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.804); catalogued as COSV101258535; called by muse, mutect2, varscan2
- EMC1 | c.458T>A p.L153H | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100617407; called by muse, mutect2
- EPB41L3 | c.668T>G p.V223G | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV100547891; called by muse, mutect2, varscan2
- F2R | c.151A>T p.K51* | Nonsense Mutation (SNP) | VAF 20/506 reads (4%) | catalogued as COSV100058229; called by muse, mutect2
- FREM2 | c.2315C>T p.T772I | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as COSV99745868; called by muse, mutect2
- GRIP1 | c.476G>C p.G159A | Missense Mutation (SNP) | VAF 24/454 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV99667395; called by muse, mutect2
- IGLV6-57 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as rs564003553, COSV101135281; called by muse, mutect2, varscan2
- LHX9 | c.1079C>T p.T360I | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100435550; called by muse, mutect2, varscan2
- MAP1A | c.6454T>A p.S2152T | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.282); catalogued as COSV100287800; called by muse, mutect2
- MAP3K20 | c.339T>G p.D113E | Missense Mutation (SNP) | VAF 66/289 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.217); catalogued as COSV100168614; called by muse, mutect2, varscan2
- MUL1 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs941628962, COSV99939256; called by muse, mutect2, varscan2
- NAPG | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV100529566; called by muse, mutect2
- NEU3 | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53638183; called by muse, mutect2, varscan2
- NUP155 | c.2270A>T p.Q757L (on ENST00000231498 / NM_153485.3; = p.Q698L on NM_004298.4) | Missense Mutation (SNP) | VAF 22/488 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV99192102; called by muse, mutect2
- OR4X1 | c.904G>T p.G302* | Nonsense Mutation (SNP) | VAF 21/134 reads (16%) | catalogued as rs775616415, COSV60722524, COSV60722812; called by muse, mutect2, varscan2
- OR5L2 | c.509G>T p.R170I | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.908); catalogued as COSV101004201; called by muse, mutect2, varscan2
- PDE1B | c.1015C>G p.H339D | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99671967; called by muse, mutect2, varscan2
- PIKFYVE | c.474T>A p.D158E | Missense Mutation (SNP) | VAF 63/279 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100009427; called by muse, mutect2, varscan2
- PLSCR5 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 15/125 reads (12%) | catalogued as rs368874624; called by muse, mutect2, varscan2
- POLL | c.283C>T p.L95F | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100149926; called by muse, mutect2, varscan2
- POLR1B | c.1135C>T p.Q379* | Nonsense Mutation (SNP) | VAF 50/359 reads (14%) | catalogued as COSV99636826; called by muse, mutect2, varscan2
- POU1F1 | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 31/251 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV55463917; called by muse, mutect2, varscan2
- PPP1R15A | c.1936A>G p.T646A | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99565755; called by muse, mutect2, varscan2
- PPP1R15A | c.1937C>T p.T646I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs764242076, COSV99565760; called by muse, varscan2
- PTGES2 | c.475T>A p.S159T | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99476209; called by muse, mutect2, varscan2
- RASSF3 | c.530C>A p.T177K | Missense Mutation (SNP) | VAF 39/315 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.773); catalogued as COSV99309113; called by muse, mutect2, varscan2
- RBM33 | c.589C>A p.L197I | Missense Mutation (SNP) | VAF 53/270 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV99840864; called by muse, mutect2, varscan2
- RLIM | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 33/250 reads (13%) | catalogued as COSV100222759, COSV60326168; called by muse, mutect2, varscan2
- RNASEH2B | c.398G>C p.G133A | Missense Mutation (SNP) | VAF 162/446 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV100352216; called by muse, mutect2, varscan2
- RUNX2 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 101/541 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100766992; called by muse, mutect2, varscan2
- SCFD2 | c.1691G>C p.G564A | Missense Mutation (SNP) | VAF 89/466 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101189153; called by muse, mutect2, varscan2
- SGCG | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 53/322 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs1188263354, COSV99522446; called by muse, mutect2, varscan2
- SGK2 | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372059009; called by muse, mutect2, varscan2
- SVOP | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); catalogued as rs759878824, COSV54469158; called by muse, mutect2, varscan2
- SYF2 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 122/438 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as rs778083415, COSV52574395; called by muse, varscan2
- TSNAXIP1 | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs775196491, COSV54648251, COSV54649983; called by muse, mutect2, varscan2
- UACA | c.1796A>T p.E599V | Missense Mutation (SNP) | VAF 123/551 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.664); catalogued as COSV100537137; called by muse, mutect2, varscan2
- UACA | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 125/556 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as COSV100537138; called by muse, mutect2, varscan2
- VPS13D | c.11860G>C p.G3954R | Missense Mutation (SNP) | VAF 33/567 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99165296; called by muse, mutect2
- VPS26C | c.446A>T p.K149M | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.326); catalogued as COSV99898195; called by muse, mutect2, varscan2
- VRK2 | c.1376C>T p.T459M | Missense Mutation (SNP) | VAF 36/439 reads (8%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs371409919; called by muse, mutect2
- YBX2 | c.1076C>A p.T359N | Missense Mutation (SNP) | VAF 85/344 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.022); catalogued as COSV99142630; called by muse, varscan2
- ZNF433 | c.620T>G p.L207W | Missense Mutation (SNP) | VAF 56/249 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100794888; called by muse, mutect2, varscan2
- ZNF521 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.82); catalogued as rs1330285345, COSV64124138; called by muse, mutect2
- ZNF830 | c.143T>A p.L48* | Nonsense Mutation (SNP) | VAF 10/182 reads (5%) | catalogued as COSV100030320; called by muse, mutect2
- ANO1 | c.1781A>C p.E594A | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2
- ARHGAP35 | c.236_248delinsA p.V79_L83delinsE | In Frame Del (DEL) | VAF 25/124 reads (20%) | called by pindel, varscan2*
- IDH3B | c.239_241del p.F80_Q81delins* | Nonsense Mutation (DEL) | VAF 16/133 reads (12%) | called by mutect2, pindel, varscan2
- MCAM | c.937del p.E313Nfs*16 | Frame Shift Del (DEL) | VAF 28/149 reads (19%) | called by mutect2, pindel, varscan2
- MUSK | c.2187_2193delinsTT p.R729Sfs*29 | Frame Shift Del (DEL) | VAF 22/89 reads (25%) | called by pindel, varscan2*
- PKN2 | c.1507del p.T503Hfs*8 | Frame Shift Del (DEL) | VAF 23/128 reads (18%) | called by mutect2, pindel, varscan2
- SERPINB12 | chr18:63567010 del A | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | called by mutect2, pindel, varscan2
- TMEM30A | c.244del p.Y82Ifs*18 | Frame Shift Del (DEL) | VAF 33/184 reads (18%) | called by mutect2, pindel, varscan2
- USP9X | c.3343T>A p.F1115I | Missense Mutation (SNP) | VAF 14/406 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- BAG5 | c.765T>C p.Y255= | Silent (SNP) | VAF 97/338 reads (29%) | catalogued as rs372338173, COSV99914552; called by muse, mutect2, varscan2
- CHRM3 | c.369T>C p.N123= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as rs764620396, COSV99697059; called by muse, mutect2, varscan2
- CNDP1 | c.1350C>G p.T450= | Silent (SNP) | VAF 25/224 reads (11%) | catalogued as COSV100722129; called by muse, mutect2, varscan2
- COL6A3 | c.8175T>C p.N2725= | Silent (SNP) | VAF 21/127 reads (17%) | catalogued as rs779148504, COSV99795682; called by muse, mutect2
- CSF2RB | c.1614C>T p.T538= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as COSV99453031; called by muse, mutect2, varscan2
- DISC1 | c.2058G>T p.L686= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as COSV100790080; called by muse, mutect2, varscan2
- IFIT3 | c.204G>A p.E68= | Silent (SNP) | VAF 19/121 reads (16%) | catalogued as COSV99259566; called by muse, mutect2, varscan2
- LRP2 | c.13533C>A p.V4511= | Silent (SNP) | VAF 71/317 reads (22%) | catalogued as COSV99785675; called by muse, mutect2, varscan2
- LRRC37B | c.363A>G p.L121= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV58953898; called by muse, mutect2
- MTA2 | c.1308T>G p.P436= | Silent (SNP) | VAF 49/303 reads (16%) | catalogued as COSV99544786; called by muse, mutect2, varscan2
- MYH9 | c.5406G>A p.K1802= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs374979658; called by muse, mutect2, varscan2
- OR10A3 | c.861G>A p.P287= | Silent (SNP) | VAF 126/660 reads (19%) | catalogued as rs200152269; called by muse, varscan2
- PRAG1 | c.2436C>A p.P812= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV100421712; called by muse, mutect2, varscan2
- RHBDD2 | c.393T>C p.D131= | Silent (SNP) | VAF 40/201 reads (20%) | catalogued as COSV99138150; called by muse, mutect2, varscan2
- RHOBTB1 | c.528G>A p.E176= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as COSV100558278; called by muse, mutect2, varscan2
- RPTOR | c.3084G>A p.V1028= | Silent (SNP) | VAF 35/162 reads (22%) | catalogued as COSV100154552; called by muse, mutect2, varscan2
- SLC22A4 | c.1650A>C p.A550= | Silent (SNP) | VAF 42/476 reads (9%) | catalogued as COSV99569063; called by muse, mutect2
- VPS4B | c.1059T>C p.V353= | Silent (SNP) | VAF 43/186 reads (23%) | catalogued as COSV99447556; called by muse, mutect2, varscan2
- ZDHHC13 | c.1056G>C p.L352= | Silent (SNP) | VAF 49/1092 reads (4%) | catalogued as COSV101239732; called by muse, mutect2
- ZMYND8 | c.3096G>A p.K1032= (on ENST00000311275 / NM_001363741.2; = p.K1006= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 55/256 reads (21%) | catalogued as COSV99519195; called by muse, mutect2, varscan2
- NDUFV3 | c.170-5443T>A | Intron (SNP) | VAF 33/155 reads (21%) | catalogued as COSV100446829; called by muse, mutect2, varscan2
